Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3GX, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3GX-01A (Primary Tumor).

[page 1 of 2]
Case Pathology Report

Pathology,

Fax:

DOB:

Physician:

Sex: F

Received:

Pathologist

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to the section "SPECIMEN" may have been added. ****

DIAGNOSIS

(A) SUPERIOR PARATHYROID GLAND:
Parathyroid tissue.

(B) TOTAL THYROID:
PAPILLARY CARCINOMA INVOLVING RIGHT LOBE, MARGINS FREE OF TUMOR.
METASTATIC PAPILLARY CARCINOMA IN ONE LYMPH NODE (1/1).
Adenomatous nodule, right lobe.

(C) RIGHT SELECTIVE NECK DISSECTION, LEVEL III, IV, V:
METASTATIC PAPILLARY CARCINOMA IN 1 LYMPH NODE OF LEVEL 4 (1/20 LYMPH NODES).

LEVEL III:

Five lymph nodes, no tumor present.

LEVEL IV LYMPH NODES:

METASTATIC PAPILLARY CARCINOMA IN 1 OF 8 LYMPH NODES.

LEVEL V LYMPH NODES:

Six lymph nodes, no tumor present.

1CB-0-3

carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 lw 11/30/11

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) SUPERIOR PARATHYROID GLAND - A minute fragment of tan soft tissue 0.1 x 0.1 x 0.1 cm. Submitted entirely for frozen in A.

*FS/DX: PARATHYROID TISSUE IDENTIFIED.

(B) TOTAL THYROID - Received is a thyroid (6.0 x 5.5 x 1.9 cm) and a portion of skeletal muscle on the anterior surface. The specimen is oriented by the surgeon.

Two well-circumscribed, partially cystic and papillary tumors are present. The larger one measures 2.5 x 2.0 x 1.5 cm and is located in the right lower lobe. The small tumor which measures 1.5 x 0.9 x 0.3 cm is located in the left lower lobe. The larger tumor has calcifications in the center. A separate pink and red well-circumscribed solid nodule is present in the right upper lobe (1.0 x 0.9 x 0.9 cm). Two tan and firm possible lymph nodes are identified measuring 1.1 x 0.7 x 0.6 cm and 0.9 x 0.7 x 0.7 cm. The remaining thyroid parenchyma is pink-purple.

INK CODE: Black-external surfaces.

SECTION CODE: B1, B2, tan-pink solid nodule in the right upper lobe; B3-B10, the larger tumor in the right lower lobe; B11, B12, one possible lymph node each; B13, B14, smaller tumor in the left lower lobe; B15, uninvolved

Page 1 of 2

History Case Pathology Report

File under: Pathology

History Case Pathology

[page 2 of 2]
History Case Pathology Report

Department of Pathology.

DOB:

Sex: F

Physician:

Tel:

Received:

Pathologist

Accession:

Case type: Surgical History

thyroid parenchyma.

(C) RIGHT SELECTED NECK DISSECTION, LEVEL III, IV, V - Received is a fragment of fibroadipose tissue (5.3 x 5.2 x 0.6 cm). The specimen is oriented by the surgeon.

Level III measures 2.5 x 2.4 x 0.8 cm. Multiple tan-pink lymph nodes are identified ranging from 0.3 cm to 1.5 x 0.6 x 0.3 cm. Level IV measures 2.8 x 1.6 x 1.1 cm. Multiple tan-pink, firm lymph nodes are identified ranging from 0.3 cm in diameter to 1.5 x 0.6 x 0.5 cm. The largest lymph node appears grossly involved by tumor. Level V measures 4.7 x 2.2 x 0.7 cm. Multiple tan-pink lymph nodes are identified ranging from 0.5 x 0.4 x 0.2 cm to 1.3 x 0.9 x 0.8 cm.

SECTION CODE: C1-C3 Level III lymph nodes (C1 three lymph nodes, C2 one lymph node, C3 one lymph node); C4-C8, level IV lymph nodes (C4 one lymph node grossly positive, C5 four lymph nodes, C6 one lymph node, C7 one lymph node, C8 one lymph node); C9-C11, level V lymph nodes, C9 and C10 one lymph node each, C11 five lymph nodes).

SNOMED CODES

M-80503 M-80506 T-B6000 T-C4200

Source: NCI Genomic Data Commons file e01474a4-02fd-4f72-a6ec-be31808ccd31 (TCGA-EL-A3GX.0449885B-38F1-423D-94F1-F34F9AD0A660.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).